MMRF case MMRF_1090 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e60be9a5-3cf1-4537-a839-e107b0f4a844

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 681 days (1.9 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.2 years (24,906 days); ISS stage: III; Days to last known disease status: 681 days (1.9 years); Days to last follow up: 681 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 94 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 73 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 134 days; Days to treatment end: 432 days (1.2 years).
   Treatment given: Therapeutic agents: Bendamustine + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 435 days (1.2 years); Days to treatment end: 681 days (1.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 681.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 0): M Protein 6.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 691 mg/dL; Immunoglobulin G 9.72 g/L; Immunoglobulin A 0.747 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 7.15 µg/mL; Hemoglobin 6.08 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 450 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.48 mmol/L; Albumin 33 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 88 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 76 mg/dL; Beta 2 Microglobulin 7.98 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 337 ×10⁹/L; Creatinine 202 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.55 mmol/L; Albumin 33 g/L; Total Protein 7.2 g/dL; Glucose 6.16 mmol/L.
- Day 183 (ECOG 0): Serum Free Immunoglobulin Light Chain, Lambda 47.8 mg/dL; Hemoglobin 7.5 mmol/L; Leukocytes 6.6 ×10⁹/L; Platelets 322 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 4.57 mmol/L.
- Day 269 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 37.7 mg/dL; Immunoglobulin G 8.52 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 3.7 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 6.9 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.67 mmol/L.
- Day 353 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 46 mg/dL; Immunoglobulin G 8.32 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 5.2 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 335 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 6.27 mmol/L.
- Day 456 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.045 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 61.2 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.58 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.65 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 4.95 mmol/L.
- Day 522: Serum Free Immunoglobulin Light Chain, Kappa 0.052 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 20.9 mg/dL; Immunoglobulin G 8.48 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 5.5 µg/mL; Lactate Dehydrogenase 5.18 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 14.6 ×10⁹/L; Absolute Neutrophil 11.1 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -5: Weight: 74 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1090_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1090_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
